Surgical pathology report (de-identified scan), TCGA case TCGA-FC-7961, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Asterand, specimen TCGA-FC-7961-01A (Primary Tumor).

[page 1 of 4]
Case ID	ID	Gross Description
		Labeled prostate and bladder neck. The specimen consists of a 50 g prostate and seminal vesicles. The gland is 3.5 cm from base to apex, 5.1 cm transversely, and 3.8 cm from anterior to posterior. The seminal vesicles are up to 4.0 cm long. The left is inked black and the right blue. The apical margin is shaved and then sectioned perpendicularly. The basal margin is similarly sectioned. The bases of the seminal vesicles are sampled. On section there is central nodular hyperplasia. The peripheral lobes are tan and spongy with a 1.5 x 0.8 cm tan-yellow mass within the right posterolateral periphery near the apex and a 1.9 x 1.1 cm mass along the left posterolateral aspect near the midpoint. No obvious extraprostatic extension is noted. Separately within the container are segments of vas deferens measuring 2.1 and 2.9 cm in length as well as a 2.2 x 1.5 x 1.0 cm rubbery tan-brown fragment presumed to be bladder neck. Upon sectioning, no masses or lesions are grossly identified.

[page 2 of 4]
Microscopic Description	Diagnosis Details	Comments
Sections from the seminal vesicle are demonstrate tumor immediately adjacent to but no into the structure. Sections from the proximal inked resection margins demonstrate tumor infiltrating close to the inked margins, but not on the ink. Definitive detrusor muscle invasion is not seen. Sections from the distal inked resection margins demonstrate tumor on the left side extending to the inked margin. There are areas of infiltrating prostatic adenocarcinoma demonstrating a Gleason score of 4 + 5 = 9. Tumor involves the right prostate lobe in a patchy fashion, the left prostate lobe extensively and the anterior prostate, where it extends to the inked margin. There is penetration of tumor into the prostatic capsule, with extension into extraprostatic fat in an established pattern in the area of the left seminal	RADICAL PROSTATECTOMY CHECKLIST  Extent of tumor:  Multifocal. Bilateral. Largest measurable focus of tumor: >2 cm. Margins:  Proximal bladder neck margin: Negative. Distal apical urethral margin: Positive. Peripheral margins: Positive, anterior margin. Extraprostatic extension: established in area of the left seminal vesicle and multifocal areas of the left lobe. Seminal vesicles involved by tumor: No, adjacent to but not into. Angiolymphatic invasion: present. Gleason score: 4 + 5 = 9 TNM: T3a N0 Mx 	

[page 3 of 4]
Formatted Path Report

PROSTATE TISSUE CHECKLIST

Specimen type: Prostatectomy
Tumor size: Not specified
Histologic type: Acinar cell adenocarcinoma
Gleason's score: $4 + 5 = 9/10$
Focality: Multiple
Laterality: Bilateral
Extraprostatic extension: Present
Lymph nodes: Not specified
Lymphatic invasion: Present
Venous invasion: Present
Seminal vesicle invasion: Absent
Margins: Involved
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: None

Laterality

Bilateral

[page 4 of 4]
Excision date

--

Source: NCI Genomic Data Commons file 3ac54e88-4364-4464-8f89-ccc517e90e2d (TCGA-FC-7961.38213CCD-4ED4-43B8-BFA0-38300DD35095.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).